Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28C, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28C-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	[ ]			
Date of Cancer Sample Procurement:	[ ]			
Histology:	[ ]			
Description of other histology:	[ ]			
Grade:	[ ]			
Mucinous:	☐ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
Signet Ring Feature:	☐ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
Histologic Heterogeneity:	☐ No	☐ Yes	☐ Unknown	
Host Response:	[ ]			
Crohn's like reaction	☐ None	☐ Yes	☐ Unknown	
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown	
Growth Pattern:	☐ Expansile	☐ Invasive	☐ Expansile and Invasive	☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown	
Angiolymphatic Invasion:	☐ No	☐ Yes	☐ Unknown	
Mutator Phenotype:	☐ No	☐ Yes	☐ Unknown	
Number of Slides	[ ]			
Garland Necrosis present:	☐ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
TIL Cells / HPF	[ ]			
Pathologist Comment:	[ ]			

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: colon, Sigmoid C18.7 *for 5/18/11*

Source: NCI Genomic Data Commons file 259edb0a-1a52-4b12-ab22-11641e9abd7a (TCGA-DM-A28C.8C4517E8-8E37-4BA2-AF3B-5621F1C572A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).